Gene-level copy-number profile of tumor specimen TCGA-56-A49D-01A from TCGA case TCGA-56-A49D, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 67.7 years (24,745 days).
Specimen TCGA-56-A49D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.33a5006e-0b1f-4eed-9ae8-b1de7eb98bcd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-56-A49D-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/64645db2-664c-412a-a64d-69fff1ae61d5

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 30,800; copy number 2: 24,042; copy number 3: 4,415; copy number 4: 132; copy number 5: 300; copy number 6: 23; copy number 8: 65; copy number 10: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-56-A49D-01A-11D-A24C-01): tumor purity 0.56, ploidy 1.61, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:198,156,994–200,214,322, 29 genes (within-gene range 0–1): NEK7, PRR13P1, AL450352.1, ATP6V1G3, AL157402.1, PTPRC, AL157402.2, PEBP1P3, MIR181A1HG, MIR181B1, MIR181A1, AC096631.2, AC096631.1, LINC01222, LINC01221, AC105941.1, LINC02789, RPL23AP16, AC099335.1, AL596266.1, AL445687.1, RNU6-778P, AL445687.2, RNU6-716P, RNU6-609P, NR5A2, RNU6-570P, AC096633.1, CCNQP1.
- chr9:79,036,413–79,726,882, 5 genes (within-gene range 0–1): KRT18P24, AL512634.1, CHCHD2P9, LNCARSR, TLE4.
- chr13:66,630,715–66,630,776, 1 gene: RNU7-87P.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 4,902 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:36,299,388–36,814,792, 7 genes, copy number 3 (within-gene range 2–3): RPL21P36, CRIM1-DT, CRIM1, AC007378.1, FEZ2, AC007363.1, VIT.
- chr3:83,937,045–198,222,513, 1,851 genes, copy number 3–10 (broad region; genes not listed).
- chr4:54,009,789–57,724,655, 86 genes, copy number 6–8 (within-gene range 2–8) (broad region; genes not listed).
- chr6:48,754,649–50,049,929, 25 genes, copy number 5 (within-gene range 2–5): AL391538.1, AL022099.1, AL589994.1, AL589994.2, FO393413.1, RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P, RHAG, CRISP2, AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112.
- chr6:134,343,307–134,504,581, 1 gene, copy number 3 (within-gene range 2–3): LINC01010.
- chr6:134,428,239–170,738,536, 610 genes, copy number 3–4 (broad region; genes not listed).
- chr8:31,275,542–32,855,666, 10 genes, copy number 3 (within-gene range 2–3): AC068672.2, AC068672.3, AC068672.1, AC090816.1, RNA5SP261, NRG1, AC068931.1, NRG1-IT1, RNA5SP262, RNA5SP263.
- chr8:36,784,324–36,936,125, 1 gene, copy number 5 (within-gene range 1–5): KCNU1.
- chr8:36,887,456–145,066,685, 1,708 genes, copy number 3–5 (within-gene range 1–5) (broad region; genes not listed).
- chr9:36,190,856–36,304,924, 4 genes, copy number 4 (within-gene range 2–4): CLTA, GNE, RNU4-53P, HMGB3P24.
- chr11:83,386,988–83,387,102, 1 gene, copy number 3: AP000446.2.
- chr11:83,643,602–83,815,263, 3 genes, copy number 3: DLG2-AS2, AP002370.1, LDHAL6DP.
- chr12:45,215,987–45,440,404, 1 gene, copy number 3 (within-gene range 1–3): ANO6.
- chr12:45,444,766–45,610,620, 3 genes, copy number 3: AC063924.1, AC079950.1, U6.
- chr13:73,399,031–73,661,891, 3 genes, copy number 3 (within-gene range 1–3): AL162376.1, MARK2P12, LINC00393.
- chr18:52,340,197–53,535,903, 1 gene, copy number 3 (within-gene range 2–3): DCC.
- chr18:53,237,101–80,247,514, 404 genes, copy number 3 (broad region; genes not listed).
- chr20:30,214,765–35,607,562, 183 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 28,477. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
